Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A94M, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-YU-A94M-01A (Primary Tumor).

Collect date: (MM/DD/YYYY)

ICD-O-3
Seminoma NOS 9061/3
Site (R) Testis NOS C62.9
9/13/14

PATHOLOGY REPORT:

PRIMARY SITE: Right testis

“Right testis”:

- . Classic seminoma
- . Neoplasia size: 2.3 x 1.4 x 1.2 cm
- . Sanguineous vascular invasion: present
- . Lymphatic vascular invasion: not detected
- . Perineural invasion: not detected
- . Intratubular neoplasia: present
- . Rete testis: compromised by neoplasia
- . Epididymis: uninvolved by neoplasia
- . Tunica albuginea: uninvolved by neoplasia
- . Spermatic cord: uninvolved by neoplasia
- . Adjacent testicular parenchyma: atrophy
- . Spermatic cord margin: uninvolved by neoplasia

PATHOLOGIC STAGING

Topography	Morphology	Stage
Testis, NOS	Seminoma, NOS	pT2

Source: NCI Genomic Data Commons file 0c849927-928d-4a0b-a950-7fbd25a2a57e (TCGA-YU-A94M-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).